Surgical pathology report (de-identified scan), TCGA case TCGA-A4-7997, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-7997-01A (Primary Tumor).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

LAB: [REDACTED]

Phone: [REDACTED]

Fax: [REDACTED]

Final Report

DIAGNOSIS

KIDNEY, LEFT PARTIAL NEPHRECTOMY:

1. Renal cell carcinoma, papillary type 1, Fuhrman grade 2 of 4
2. Tumor is confined to the kidney
3. Tumor focally extends to the inked parenchymal resection margin
4. Negative for lymphatic/vascular invasion by tumor
5. Please see kidney cancer staging parameters below

COMMENT:

The diagnosis was discussed with [REDACTED] on [REDACTED] at [REDACTED]

KIDNEY STAGING PARAMETERS

Case number: [REDACTED] Patient name: [REDACTED]

Final TNM: pT1bNXM0

[REDACTED] stage: I

MACROSCOPIC

PROCEDURE

Partial nephrectomy

SPECIMEN LATERALITY

Left

TUMOR SITE

Not specified

TUMOR SIZE

4.3 cm

TUMOR FOCALITY

Unifocal

MACROSCOPIC EXTENT OF TUMOR

Tumor limited to kidney

MICROSCOPIC

HISTOLOGIC TYPE

Papillary renal cell carcinoma

TUMOR NECROSIS

Not identified

HISTOLOGICAL GRADE

G2: Nuclei slightly irregular, approximately 15 um; nucleoli evident

MICROSCOPIC EXTENT OF TUMOR

Tumor limited to kidney

LYMPHATIC VASCULAR INVASION

Not identified

MARGINS

Involved by carcinoma

Involved margin: Renal parenchymal margin

[page 2 of 3]
PATHOLOGIC STAGING

EXTENT OF INVASION

pT1b. (Tumor more than 4 cm but not more than 7 cm in greatest dimension limited to the kidney)

REGIONAL LYMPH NODES

pNX. (Regional lymph nodes cannot be assessed)

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT1bNXM0

stage: I

* The pathologic stage presumes no lymph node metastasis.

** The pathologic stage presumes no distant metastasis.

Attending Pathologist:

CLINICAL INFORMATION

History of left renal mass

SPECIMEN/GROSS DESCRIPTION

SOURCE: Left partial kidney nephrectomy

The specimen is received fresh from the OR labeled "left partial nephrectomy." It consists of a 49 gram, 4.7 x 4.3 x 4.3 cm rubbery ovoid wedge renal parenchyma. The intact, smooth capsular surface with thin fatty adhesions is inked blue and the predominantly smooth, focally coarse resection margin is inked black. The tissue is serially cross sectioned and the cut surfaces display a 4.3 x 4 x 4 cm tumor bulging the capsule and located less than 0.1 cm from the black inked margin. A representative section of the margin is frozen on one block.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Papillary renal cell carcinoma forming a 4.3 cm greatest dimension tumor, completely excised. Margin is negative for malignancy." is rendered by

The cut surfaces of the tumor are yellow, tan, red, variegated and vaguely lobulated with a thin fibrous capsule. The tumor constitutes at least 90% of the specimen volume. The scant renal parenchyma at the periphery of the margin is grossly unremarkable.

Representative sections to include all of the closest black inked renal margin are submitted in nine cassettes as follows:

1. Frozen section residue
- 2-9. Renal tumor with black inked margin, blue inked capsule and adjacent normal appearing renal parenchyma

Note: Representative tissue is banked for possible study. Representative tissue is also apportioned into one vial of RPMI and sent to cytogenetics to hold.

This case is accessioned in FileMaker Pro.

Gross dictation by:

MICROSCOPIC

The microscopic appearance substantiates the diagnosis. The positive margin is noted on the permanent section. Portions of the specimen not submitted for frozen section.

[page 3 of 3]
Dictation by: [REDACTED] Transcribed by: [REDACTED]

Interpreted at [REDACTED]

COLLECTED: [REDACTED] ACCESSIONED: [REDACTED] SIGNED: [REDACTED]

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED] on [REDACTED] - Lab and Collection Information

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED] on [REDACTED] Order Result History Report.

Lab Status
Order Complete [REDACTED]

Result Information

Result Date and Time	Status	Provider Status
[REDACTED]	Final result	Ordered

Lab Information

Lab
[REDACTED]

Order Details

Parent Order ID	Child Order ID
[REDACTED]	[REDACTED]

Entry Date

[REDACTED]

Specimen Information

Specimen Source	Collection Date	Collection Time
Other	[REDACTED]	[REDACTED]

Audit Trail

Action	User	Date/Time
Order Printed	[REDACTED]	[REDACTED]
Order Printed	[REDACTED]	[REDACTED]

MyChart Status:

This result is currently not released to MyChart.

Order

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED] (Order [REDACTED])

Order Information

Date	Ordering User	Department
[REDACTED]	[REDACTED]	[REDACTED]

Authorizing Provider

[REDACTED]

Source: NCI Genomic Data Commons file 2f90a126-944e-4ff6-83ad-0e572b8ce4aa (TCGA-A4-7997.1080D11B-8DCF-4690-A930-F3E7EFA5E777.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).